Somatic mutation profile of tumor specimen TCGA-AX-A1CP-01A (aliquot TCGA-AX-A1CP-01A-11D-A135-09) from TCGA case TCGA-AX-A1CP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 84.2 years (30,737 days).
Specimen TCGA-AX-A1CP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f633701-68f1-44d8-b79c-7d86db64c84e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CP-10A (Blood Derived Normal), aliquot TCGA-AX-A1CP-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b706dd-2d84-4a26-bb53-feca63afd84c

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, RNA 1, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 47/76 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 44/69 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WAS | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs132630269, CD043694, CM951316, COSV64997572; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.7387A>G p.I2463V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV54963606; called by muse, mutect2, varscan2
- ASXL2 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55464670; called by muse, mutect2, varscan2
- ATG4B | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.137); catalogued as COSV60351221; called by muse, mutect2, varscan2
- COL11A1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs148464130; called by muse, mutect2, varscan2
- DNM1L | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460019135, COSV56776840; called by muse, mutect2, varscan2
- FAM47A | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60495968, COSV60498995; called by muse, mutect2, varscan2
- GPC6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.858); catalogued as rs192508779, COSV65524909; called by muse, mutect2, varscan2
- HRNR | c.2628C>A p.H876Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs370407108, COSV64258970; called by muse, mutect2, varscan2
- IL13RA1 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65424929; called by muse, mutect2, varscan2
- ISLR2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62303161; called by muse, mutect2, varscan2
- LILRB5 | c.33C>T p.L11= | Splice Region (SNP) | VAF 30/38 reads (79%) | catalogued as rs532597420, COSV60260054; called by muse, mutect2, varscan2
- MAP7D3 | c.926T>G p.V309G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60172016; called by muse, mutect2
- NDN | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs1253647206, COSV59360966; called by muse, mutect2, varscan2
- NR1H4 | c.704A>G p.N235S (on ENST00000551379 / NM_001206993.2; = p.N221S on NM_005123.4) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV51855309; called by muse, mutect2
- OR9A2 | c.892C>G p.R298G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100628237, COSV63307007; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.325); catalogued as COSV53454945; called by muse, mutect2, varscan2
- SCN11A | c.3571G>A p.V1191I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199670122, COSV56574624, COSV56575442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61989513; called by muse, mutect2, varscan2
- SYT3 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58898338; called by muse, mutect2, varscan2
- FOXA2 | c.1040_1054delinsG p.A347Gfs*10 (on ENST00000377115 / NM_153675.3; = p.A353Gfs*10 on NM_021784.5) | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by pindel, varscan2*
- MRPL45 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 3/55 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- BSN | c.3336G>A p.A1112= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs777905798, COSV56524845; called by muse, mutect2, varscan2
- NEK7 | c.67C>A p.R23= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs779021260, COSV66312338; called by muse, mutect2, varscan2
- PRDM9 | c.366G>A p.A122= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs766083673, COSV57008152, COSV57010953; called by muse, mutect2, varscan2
- RHOT2 | c.1245C>T p.S415= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs762549610, COSV53473692; called by muse, mutect2, varscan2
- SH3KBP1 | c.906C>T p.I302= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs748098458, COSV65643760; called by muse, mutect2, varscan2
- ZNF833P | n.993dup | RNA (INS) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
